Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3851, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3851-01A (Primary Tumor).

Diagnosis:

The material available is an invasive, moderately differentiated adenocarcinoma of the colon, G2, with penetration of all parietal layers pT3, with vascular infiltration L1, V1, with free resection margins locally R0 and free lymph nodes (pN0, 0 of 14).

Remark:

In Block D, the polyps were examined separately. They were found to be serrated adenomas with dentate form cylindrical epithelia and goblet cells, as well as bleeding in the stroma. The polyps did not show any evidence of invasive structures.

Tumor classification:

ICDO-DA-M 8140/3

G2

pT3, pN0 (0/14)

Locally R0

M classification in oncology conference.

Source: NCI Genomic Data Commons file fc6100ec-4c8e-4ee4-8598-8472a236174b (TCGA-AA-3851.57BEDEE0-2765-45B0-8472-29E5464034D2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).